Somatic mutation profile of tumor specimen TCGA-HD-8314-01A (aliquot TCGA-HD-8314-01A-11D-2394-08) from TCGA case TCGA-HD-8314, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 58.9 years (21,517 days).
Specimen TCGA-HD-8314-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e368afbd-d7bb-4b9d-971b-9e6a893d9c59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-8314-10A (Blood Derived Normal), aliquot TCGA-HD-8314-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53159e9f-9198-4282-8325-26ea24ea62ae

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Nonsense Mutation 3, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201212787, COSV55777752; called by muse, mutect2, varscan2
- AFDN | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100653122; called by muse, mutect2, varscan2
- ANO7 | c.2654G>A p.R885Q (on ENST00000274979; = p.R831Q on NM_001370694.2) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as rs764545838, COSV99238644; called by muse, mutect2, varscan2
- APLP2 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99599786; called by muse, mutect2, varscan2
- ATRNL1 | c.2284G>C p.V762L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100745962; called by muse, mutect2, varscan2
- C2CD4A | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100831030; called by mutect2, varscan2
- CA10 | c.522G>C p.K174N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); catalogued as COSV99563478; called by muse, mutect2, varscan2
- CD200R1L | c.672G>C p.L224F | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1242173718, COSV101236601; called by muse, mutect2
- CRNKL1 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as COSV99845359; called by muse, mutect2, varscan2
- DNAAF3 | c.931C>G p.Q311E (on ENST00000524407 / NM_001256715.2; = p.Q358E on NM_178837.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.074); catalogued as rs1435089653, COSV100787947; called by muse, mutect2
- FAM135B | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52737724, COSV99424890, COSV99426619; called by muse, mutect2, varscan2
- FLNC | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100368259; called by muse, mutect2, varscan2
- GASK1B | c.815T>C p.L272S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV99647793; called by muse, mutect2, varscan2
- GDF2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1555208722; called by muse, mutect2, varscan2
- GGN | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as COSV99287513; called by muse, mutect2, varscan2
- GRM7 | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1114167301, COSV63138097; called by muse, mutect2, varscan2
- HFM1 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as rs772600370, COSV99646168; called by muse, mutect2
- HSP90B1 | c.1866G>T p.M622I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV100236586; called by muse, mutect2, varscan2
- IGF2R | c.5576C>T p.S1859L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100807570; called by muse, mutect2, varscan2
- IGSF10 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99180029; called by muse, mutect2, varscan2
- INPP4B | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV99525087; called by muse, mutect2, varscan2
- LRP6 | c.4039C>G p.H1347D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs763865658, COSV99743586; called by muse, mutect2
- LRRC37B | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100496318; called by muse, mutect2, varscan2
- LRRC37B | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58952897; called by muse, mutect2
- MAP1B | c.187A>C p.I63L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99702541; called by muse, varscan2
- MKI67 | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.542); catalogued as COSV100896670, COSV64074842; called by muse, mutect2, varscan2
- MYH1 | c.4795G>C p.E1599Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV56855184, COSV99876205; called by muse, mutect2, varscan2
- OR2M5 | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV100822833, COSV63545665; called by muse, mutect2
- PASD1 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.272); catalogued as COSV100949426; called by muse, mutect2, varscan2
- PCDHA5 | c.797C>G p.S266* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as rs782650133, COSV100972356, COSV65356956; called by muse, mutect2, varscan2
- PDIA5 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV100299483; called by muse, mutect2
- PRKCA | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV101151255; called by muse, mutect2, varscan2
- PROS1 | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV101260585; called by muse, mutect2, varscan2
- RAB20 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs370664083, COSV99940907; called by muse, mutect2, varscan2
- RASA2 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99656286; called by muse, mutect2, varscan2
- RYR2 | c.14368C>T p.R4790* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV63702045; called by muse, mutect2, varscan2
- SERPINF1 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99628872; called by muse, mutect2, varscan2
- SLC17A8 | c.1142A>C p.Q381P | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV100035634; called by muse, mutect2, varscan2
- SLC1A6 | c.1172C>G p.S391W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55670952; called by muse, mutect2
- SPACA7 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201471740, COSV99366702; called by muse, mutect2, varscan2
- ST3GAL3 | c.697G>A p.E233K (on ENST00000361392 / NM_174964.4; = p.E218K on NM_006279.5) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.913); catalogued as COSV99495538, COSV99495639, COSV99496130; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | PolyPhen benign (0.21); catalogued as COSV100083870; called by muse, mutect2, varscan2
- STAT3 | c.1541C>A p.S514Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99232863; called by muse, mutect2, varscan2
- STX5 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV99586969; called by muse, mutect2, varscan2
- SYCE2 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99535960; called by muse, mutect2, varscan2
- SYNPO | c.2221G>T p.E741* (on ENST00000394243 / NM_001166208.2; = p.E497* on NM_007286.6) | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100302230; called by muse, mutect2, varscan2
- TLN2 | c.5536G>A p.E1846K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.066); catalogued as rs1208636481, COSV100169296; called by muse, mutect2, varscan2
- TMCC2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as rs148387041; called by muse, mutect2, varscan2
- TOGARAM1 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as COSV100818098; called by muse, mutect2, varscan2
- TRIM68 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV100331743; called by muse, mutect2, varscan2
- TTN | c.56635G>A p.E18879K (on ENST00000591111; = p.E11455K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | PolyPhen benign (0.033); catalogued as COSV100617873; called by muse, mutect2, varscan2
- UBOX5 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418099; called by muse, mutect2, varscan2
- WDFY3 | c.1655C>G p.T552S | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.313); catalogued as COSV99883999; called by muse, mutect2, varscan2
- WDR55 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as rs1188659125, COSV100845593; called by muse, mutect2
- WWTR1 | c.906-1G>A p.X302_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | catalogued as COSV100640889; called by mutect2, varscan2
- ZNF385D | c.870G>T p.R290S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99875086; called by muse, mutect2, varscan2
- ABCA1 | c.4842C>T p.L1614= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs976043817, COSV101037151; called by muse, mutect2, varscan2
- ATP2C1 | c.942C>T p.V314= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as COSV100146793; called by muse, mutect2, varscan2
- C19orf47 | c.429C>T p.I143= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- CEACAM7 | c.468T>C p.N156= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV99137260; called by muse, mutect2, varscan2
- CHAD | c.408T>G p.T136= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV99366231; called by muse, mutect2, varscan2
- CHRNA4 | c.1488C>T p.D496= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs776563173, COSV64718562; called by muse, mutect2
- CNTN6 | c.2151C>T p.L717= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs369886465; called by muse, mutect2, varscan2
- GOLGB1 | c.1878A>C p.P626= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV100511084; called by muse, mutect2
- KDM6B | c.3195G>A p.P1065= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs372614245; called by muse, mutect2, varscan2
- KHDC4 | c.1380G>A p.Q460= | Silent (SNP) | VAF 15/184 reads (8%) | catalogued as COSV100850820; called by muse, mutect2
- MKKS | c.216C>T p.P72= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100726295; called by muse, mutect2, varscan2
- MUC16 | c.1020C>T p.A340= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs778792098, COSV101199336; called by muse, mutect2, varscan2
- PKD1 | c.7251G>C p.L2417= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- PRKCE | c.405G>A p.S135= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as rs779253222, COSV100076463; called by muse, mutect2, varscan2
- REEP2 | c.447C>T p.F149= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV54734508; called by muse, mutect2, varscan2
- SSTR4 | c.126G>A p.A42= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99658632; called by muse, varscan2
- WDR49 | c.492C>T p.I164= (on ENST00000308378 / NM_001366158.1; = p.I505= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1422618864, COSV100393031; called by muse, mutect2, varscan2
- ZNF267 | c.183G>A p.E61= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV56250817; called by muse, mutect2, varscan2
- ZNF713 | c.534G>A p.L178= (on ENST00000633730 / NM_001366796.2; = p.L191= on NM_182633.3) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV101448740; called by muse, mutect2, varscan2
- EIF4G1 | c.-91-148C>T | Intron (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100071960; called by muse, mutect2, varscan2
